Somatic mutation profile of tumor specimen MMRF_2503_1_BM_CD138pos (aliquot MMRF_2503_1_BM_CD138pos_T1_KHS5U_L11624) from MMRF case MMRF_2503, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,601 days).
Specimen MMRF_2503_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a149c8-0ad2-4298-b15e-c11ef6dd06a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2503_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2503_1_PB_Whole_C2_KHS5U_L11625; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d25ec8f1-35a3-4b46-85d1-686855925488

The open-access MAF lists 147 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 40, Intron 19, Silent 13, RNA 6, Nonsense Mutation 5, 5'Flank 5, 5'UTR 3, Frame Shift Del 2, Splice Region 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370445373, COSV60258220; called by muse, mutect2, varscan2
- ATP7B | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349853812; called by muse, mutect2, varscan2
- BABAM2 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 134/580 reads (23%) | catalogued as rs752630548, COSV56223704; called by muse, mutect2, varscan2
- CACNA1E | c.6229C>T p.R2077C (on ENST00000367573 / NM_001205293.3; = p.R2034C on NM_000721.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs370905391; called by muse, mutect2, varscan2
- COL6A1 | c.1063C>A p.Q355K | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.755); catalogued as COSV100720102; called by muse, mutect2
- DIS3 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs571401803, COSV58327351; called by muse, mutect2, varscan2
- DUSP2 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 117/201 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752250965; called by muse, mutect2, varscan2
- F13A1 | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 27/433 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760467093; called by muse, mutect2
- FAM83F | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs762446693, COSV60999809; called by muse, mutect2, varscan2
- GABBR1 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.264); catalogued as rs752173788, COSV63542179; called by muse, mutect2, varscan2
- IGHV3-30 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); catalogued as rs561864589; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs559078152; called by muse, varscan2
- IGLV3-1 | c.281G>C p.S94T | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as rs375164349; called by muse, varscan2
- MAP2 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 30/276 reads (11%) | catalogued as COSV99558600, COSV99561504; called by muse, mutect2, varscan2
- MEOX1 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV59356730; called by muse, mutect2, varscan2
- MPDZ | c.4138A>T p.I1380F | Missense Mutation (SNP) | VAF 33/503 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180799439; called by muse, mutect2
- MROH7 | c.214del p.A72Pfs*58 | Frame Shift Del (DEL) | VAF 33/147 reads (22%) | catalogued as COSV59868375; called by mutect2, pindel, varscan2
- MSMP | c.239+5G>A | Splice Region (SNP) | VAF 16/566 reads (3%) | catalogued as rs1396959412; called by muse, mutect2
- MUC4 | c.12724G>T p.A4242S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.096); catalogued as rs11915904; called by muse, varscan2
- ODF3L1 | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs375002942; called by muse, mutect2, varscan2
- OR8B8 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV60143936; called by muse, mutect2, varscan2
- PCDHB5 | c.2372G>A p.S791N | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1258501515, COSV50648142; called by muse, mutect2, varscan2
- PCSK9 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149139428; called by muse, mutect2, varscan2
- PNLIP | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV65042349; called by muse, mutect2, varscan2
- RSPO3 | c.666dup p.P223Tfs*2 | Frame Shift Ins (INS) | VAF 46/82 reads (56%) | catalogued as rs1049009076; called by mutect2, varscan2
- RYR1 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751728775, COSV62093472; called by muse, mutect2
- SLC22A3 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs1288979106; called by muse, mutect2, varscan2
- TACC3 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as COSV99046162; called by muse, mutect2, varscan2
- TGFBR3 | c.2329+1G>C p.X777_splice | Splice Site (SNP) | VAF 8/79 reads (10%) | catalogued as COSV53029238; called by muse, mutect2, varscan2
- USP29 | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1477254187; called by muse, mutect2
- XPOT | c.74T>C p.F25S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1259831352; called by muse, mutect2, varscan2
- ZNF407 | c.2891A>G p.N964S | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1301024031; called by muse, mutect2, varscan2
- ACTB | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 196/356 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); called by muse, varscan2
- ANKRD50 | c.3326C>T p.S1109F | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AP002512.3 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- ATP6V1B1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2
- CDK12 | c.2289G>C p.E763D | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EIF4A3 | c.63_65del p.E21del | In Frame Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- FHDC1 | c.1342A>C p.I448L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GIT1 | c.1299_1306del p.A434Gfs*13 | Frame Shift Del (DEL) | VAF 32/135 reads (24%) | called by mutect2, pindel, varscan2
- HES5 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HMCN2 | c.9313G>T p.D3105Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LOXHD1 | c.1656G>T p.M552I | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- NCAPG | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OVCH1 | c.2463T>G p.N821K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PDE10A | c.1120A>C p.T374P | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPEF1 | c.994T>G p.F332V | Missense Mutation (SNP) | VAF 131/137 reads (96%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPRD | c.1728A>C p.K576N | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- RFX7 | c.1536G>A p.M512I (on ENST00000559447 / NM_001368074.1; = p.M609I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/488 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RP1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SOSTDC1 | c.532A>C p.N178H | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SP140 | c.237+5G>A | Splice Region (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SYCE1 | c.605T>G p.V202G (on ENST00000343131 / NM_001143764.3; = p.V166G on NM_130784.3) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SYNDIG1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRMT9B | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- UNC45A | c.2105A>C p.D702A | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VIL1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 234/382 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ZNF471 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- ZNF613 | c.1544C>T p.S515F (on ENST00000293471 / NM_001031721.4; = p.S479F on NM_024840.4) | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- APOA5 | c.600C>T p.S200= | Silent (SNP) | VAF 41/152 reads (27%) | called by muse, mutect2, varscan2
- CHPF2 | c.2052C>T p.A684= | Silent (SNP) | VAF 60/187 reads (32%) | called by muse, mutect2, varscan2
- DAPK1 | c.3948G>T p.L1316= | Silent (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- MCPH1 | c.1674G>C p.L558= | Silent (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- MUC3A | c.1170C>T p.T390= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- MYT1 | c.2727C>G p.A909= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- OR10X1 | c.747C>G p.G249= | Silent (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- PAX3 | c.972C>T p.P324= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- PLCB1 | c.1608C>T p.A536= | Silent (SNP) | VAF 102/201 reads (51%) | catalogued as rs1265934434; called by muse, mutect2, varscan2
- THBD | c.1296C>T p.I432= | Silent (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- TMPRSS13 | c.1467C>T p.Y489= | Silent (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- ZNF84 | c.1710G>T p.P570= | Silent (SNP) | VAF 65/153 reads (42%) | called by muse, mutect2, varscan2
- ZRANB1 | c.1152A>G p.P384= | Silent (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2, varscan2
- AADACL3 | c.*2245T>C | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- AC006971.1 | n.1509T>A | RNA (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- ACTB | c.123+63G>A | Intron (SNP) | VAF 143/218 reads (66%) | called by muse, varscan2
- BCL7A | chr12:122021256 G>C | 5'Flank (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021662 G>A | 5'Flank (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- CCDC171 | c.3600+113T>C | Intron (SNP) | VAF 17/245 reads (7%) | called by muse, mutect2
- CDON | c.*3761T>C | 3'UTR (SNP) | VAF 63/346 reads (18%) | called by muse, mutect2, varscan2
- CELF4 | c.657+40C>T | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CLNK | c.*1384A>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- CTSZ | c.638+52C>T | Intron (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2
- CUBN | c.*460C>A | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- CXXC1 | c.3+74C>T | Intron (SNP) | VAF 90/594 reads (15%) | called by muse, mutect2, varscan2
- CYP3A43 | c.433-168C>T | Intron (SNP) | VAF 12/29 reads (41%) | catalogued as rs934202463; called by muse, mutect2
- DGKI | chr7:137389384 A>G | 3'Flank (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- DHX40P1 | n.985A>G | RNA (SNP) | VAF 68/153 reads (44%) | called by muse, mutect2, varscan2
- DLG3 | c.*2785G>T | 3'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- DNAAF4 | c.*331G>A | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by mutect2, varscan2
- DOC2A | c.342+37dup | Intron (INS) | VAF 14/50 reads (28%) | called by pindel, varscan2
- DPP9 | c.2244+264G>T | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- EML1 | c.*1680A>C | 3'UTR (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ERVV-1 | chr19:53010056 C>G | 5'Flank (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- FAIM2 | c.*2273C>T | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- FAM133A | c.*1124A>G | 3'UTR (SNP) | VAF 44/45 reads (98%) | called by muse, mutect2, varscan2
- FGFRL1 | c.*672G>C | 3'UTR (SNP) | VAF 23/576 reads (4%) | called by muse, mutect2
- FIGN | c.*4025T>C | 3'UTR (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- FOXK1 | c.*171G>A | 3'UTR (SNP) | VAF 42/192 reads (22%) | catalogued as rs962239432, COSV61066354; called by muse, mutect2, varscan2
- FRMD6 | c.*894T>A | 3'UTR (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- GABRA6 | c.674-39G>C | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- GABRB2 | c.*5225A>T | 3'UTR (SNP) | VAF 112/119 reads (94%) | called by muse, mutect2, varscan2
- GLT6D1 | c.*119G>A | 3'UTR (SNP) | VAF 36/110 reads (33%) | catalogued as rs560408659; called by muse, mutect2, varscan2
- GPATCH2 | c.1098+1433G>A | Intron (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- GRM1 | c.*467A>T | 3'UTR (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- GULP1 | c.*1488_*1491del | 3'UTR (DEL) | VAF 19/83 reads (23%) | catalogued as rs748900318; called by mutect2, pindel, varscan2
- GYPA | c.232+126G>T | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- HABP4 | c.*1022C>T | 3'UTR (SNP) | VAF 89/146 reads (61%) | catalogued as rs16910909; called by muse, mutect2, varscan2
- HSPA5 | c.-178G>C | 5'UTR (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- IGHJ6 | chr14:105863445 C>T | 5'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as rs547529013; called by muse, mutect2, varscan2
- KCNE3 | c.*215T>A | 3'UTR (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- KLHL8 | c.*812A>G | 3'UTR (SNP) | VAF 35/107 reads (33%) | catalogued as rs1333623702; called by muse, mutect2, varscan2
- KLKB1 | c.*53T>C | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- LINC01517 | n.1789G>A | RNA (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- LIPT2 | chr11:74496946 A>G | 5'Flank (SNP) | VAF 45/222 reads (20%) | catalogued as rs1361468531; called by muse, mutect2, varscan2
- LRRC8A | c.*969C>A | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- MAN1A2 | c.-506C>G | 5'UTR (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- MDGA1 | c.*4321G>T | 3'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- MIB1 | c.*3454dup | 3'UTR (INS) | VAF 10/33 reads (30%) | catalogued as rs996094861; called by mutect2, pindel
- MYLIP | c.*1081G>T | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- NCOA7 | c.*560T>C | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- NTRK2 | c.*4C>A | 3'UTR (SNP) | VAF 24/448 reads (5%) | catalogued as COSV52863335; called by muse, mutect2
- OR10J8P | n.177G>A | RNA (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- OSBPL3 | c.*3487dup | 3'UTR (INS) | VAF 13/79 reads (16%) | catalogued as rs376082395; called by mutect2, pindel, varscan2
- PARP9 | c.2185+2825C>T | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- PGAP1 | c.*1135G>A | 3'UTR (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- PKN1 | c.757-30C>T | Intron (SNP) | VAF 20/40 reads (50%) | catalogued as rs1465388352; called by muse, mutect2, varscan2
- POMT1 | c.*36C>T | 3'UTR (SNP) | VAF 57/153 reads (37%) | catalogued as rs368777622; called by muse, mutect2, varscan2
- REPS1 | c.-534G>A | 5'UTR (SNP) | VAF 14/105 reads (13%) | catalogued as rs1449641435; called by muse, mutect2, varscan2
- RGS19 | c.*399C>G | 3'UTR (SNP) | VAF 51/333 reads (15%) | called by muse, mutect2, varscan2
- RGS19 | c.*168C>A | 3'UTR (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- RGS19 | c.-68-11C>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- RNF216 | c.202-80A>C | Intron (SNP) | VAF 110/524 reads (21%) | called by muse, mutect2, varscan2
- RNMT | c.*231T>C | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- SCD5 | c.569+20029C>A | Intron (SNP) | VAF 35/84 reads (42%) | catalogued as rs1478804402; called by muse, mutect2, varscan2
- SH3TC1 | c.3131+466T>C | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- SLC32A1 | c.*573C>G | 3'UTR (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- SPAG16-DT | n.532C>A | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- SSPOP | n.10524G>A | RNA (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SYNE3 | c.*8315A>G | 3'UTR (SNP) | VAF 42/300 reads (14%) | called by muse, mutect2, varscan2
- TEAD1 | c.*303A>C | 3'UTR (SNP) | VAF 102/171 reads (60%) | called by muse, mutect2, varscan2
- TEAD1 | c.*1457C>A | 3'UTR (SNP) | VAF 91/145 reads (63%) | called by muse, mutect2, varscan2
- TRAF5 | c.*824C>T | 3'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- TRIM41 | c.1291+40T>C | Intron (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- USH1C | c.1284+7592T>C | Intron (SNP) | VAF 17/100 reads (17%) | catalogued as rs757006603; ClinVar: likely benign; called by muse, mutect2, varscan2
- YWHAH | c.*42C>A | 3'UTR (SNP) | VAF 21/391 reads (5%) | called by muse, mutect2
- ZNF813 | c.*1201C>A | 3'UTR (SNP) | VAF 31/338 reads (9%) | called by muse, mutect2
